Somatic mutation profile of tumor specimen TCGA-TQ-A7RK-01A (aliquot TCGA-TQ-A7RK-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.4 years (10,742 days).
Specimen TCGA-TQ-A7RK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d721213-1f37-484a-af82-0a2ca2d38b48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RK-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RK-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/693e8ac5-a808-4109-9120-0b9ea4134084

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 2, In Frame Del 2, Nonsense Mutation 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 68/182 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 114/120 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALOX5 | c.1966_1968del p.K656del | In Frame Del (DEL) | VAF 52/188 reads (28%) | catalogued as rs750469694; called by pindel, varscan2
- ATRX | c.4291C>T p.Q1431* | Nonsense Mutation (SNP) | VAF 127/146 reads (87%) | catalogued as COSV100970319; called by muse, mutect2, varscan2
- C2orf16 | c.5179C>T p.R1727C | Missense Mutation (SNP) | VAF 228/503 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); catalogued as rs745938050, COSV100820671, COSV62676703; called by muse, mutect2, varscan2
- C4orf19 | c.932A>C p.D311A | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99448466; called by muse, mutect2, varscan2
- CPAMD8 | c.3511G>A p.G1171R (on ENST00000651564; = p.G1124R on NM_015692.5) | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760356652, COSV101488444; called by muse, mutect2, varscan2
- G2E3 | c.1072A>T p.K358* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs778769231, COSV52840527; called by muse, mutect2, varscan2
- GPER1 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866836; called by muse, mutect2, varscan2
- KLHL2 | c.1747T>G p.Y583D | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99899793; called by muse, mutect2, varscan2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- OR4A5 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100157005; called by muse, mutect2, varscan2
- POLR1E | c.1087G>A p.G363R (on ENST00000377792 / NM_001282766.1; = p.G301R on NM_022490.4) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV66772217; called by muse, mutect2
- SLC1A6 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs896326116, COSV55674395; called by muse, mutect2, varscan2
- SUMF1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1249221556, COSV55994224; called by muse, mutect2
- TTN | c.11548C>G p.L3850V (on ENST00000591111; = p.L3804V on NM_003319.4) | Missense Mutation (SNP) | VAF 47/169 reads (28%) | catalogued as COSV100601370; called by muse, mutect2, varscan2
- C12orf29 | c.853_855del p.V285del | In Frame Del (DEL) | VAF 43/158 reads (27%) | called by mutect2, pindel, varscan2
- RFTN1 | c.928_931del p.T310* | Frame Shift Del (DEL) | VAF 116/463 reads (25%) | called by mutect2, pindel, varscan2
- WFIKKN2 | c.560del p.P187Hfs*41 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- ARHGAP29 | c.1812A>C p.T604= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV99557821; called by muse, mutect2, varscan2
- COL5A1 | c.363C>T p.N121= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs369180922; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRIQ1 | c.4896C>T p.Y1632= | Silent (SNP) | VAF 67/192 reads (35%) | catalogued as COSV101279814; called by muse, mutect2, varscan2
- OR5T1 | c.600T>C p.S200= | Silent (SNP) | VAF 185/434 reads (43%) | catalogued as COSV100478902, COSV57301674, COSV57301917; called by muse, mutect2, varscan2
- LEKR1 | c.*852T>C | 3'UTR (SNP) | VAF 44/109 reads (40%) | catalogued as rs1170930370, COSV100738731; called by muse, mutect2, varscan2
- RPL31P57 | n.148C>T | RNA (SNP) | VAF 20/118 reads (17%) | catalogued as rs367584045; called by muse, mutect2, varscan2
